Somatic mutation profile of tumor specimen TCGA-77-A5GB-01B (aliquot TCGA-77-A5GB-01B-11D-A27K-08) from TCGA case TCGA-77-A5GB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-77-A5GB-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4617ca09-92ee-45fd-819d-bb0fbfe482c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5GB-10A (Blood Derived Normal), aliquot TCGA-77-A5GB-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b3bac66-b0dc-45ff-a766-98f2ae330b25

The open-access MAF lists 135 somatic variants for this specimen: 98 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 34, Nonsense Mutation 8, Splice Site 1, Intron 1, 3'UTR 1, IGR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.379G>T p.G127* | Nonsense Mutation (SNP) | VAF 24/161 reads (15%) | hotspot (GDC flag); catalogued as rs587781255, CM128490, COSV64289445, COSV64291964; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2
- ACP6 | c.978-1G>T p.X326_splice | Splice Site (SNP) | VAF 19/134 reads (14%) | catalogued as COSV100984167, COSV65077903; called by muse, mutect2, varscan2
- APC | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99965856; called by muse, mutect2, varscan2
- APOD | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV100581053; called by muse, mutect2
- APPBP2 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs757905099, COSV50030509; called by muse, mutect2, varscan2
- ASTE1 | c.930C>A p.F310L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99393657; called by muse, mutect2, varscan2
- ASTE1 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99393664; called by muse, mutect2, varscan2
- BRD4 | c.1200G>C p.M400I | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54581997; called by muse, mutect2
- BSND | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100987609, COSV100987652; called by muse, mutect2
- BTD | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100329448; called by muse, mutect2, varscan2
- C16orf87 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99587467; called by muse, mutect2
- C19orf73 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99674397; called by muse, mutect2, varscan2
- CCDC7 | c.1798C>G p.Q600E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); catalogued as COSV100178954, COSV56551755; called by muse, mutect2, varscan2
- CD9 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV99152806; called by muse, mutect2, varscan2
- CDC42EP2 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV99659098; called by muse, mutect2, varscan2
- CDS1 | c.1287G>C p.Q429H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99880422; called by muse, mutect2, varscan2
- CFAP100 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777814056, COSV100729108; called by muse, mutect2, varscan2
- CHD9 | c.5649G>C p.L1883F | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99528788; called by muse, mutect2
- CNOT2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as COSV57501995, COSV99973149; called by muse, mutect2, varscan2
- COL11A1 | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100615396; called by muse, mutect2
- CRACD | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs1036293367, COSV51726277; called by muse, mutect2, varscan2
- CRIP3 | c.464A>T p.H155L | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99240157; called by muse, mutect2
- DDX27 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV100872196; called by muse, mutect2, varscan2
- DGKE | c.515T>A p.L172* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99400712; called by muse, mutect2, varscan2
- DNAH8 | c.13001C>G p.S4334C | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.778); catalogued as COSV100543635; called by muse, mutect2, varscan2
- DSC1 | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV99937309; called by muse, mutect2, varscan2
- DSG4 | c.1286T>C p.I429T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100355471; called by muse, mutect2, varscan2
- DUS2 | c.690T>G p.F230L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV100732428; called by muse, mutect2, varscan2
- EFCAB7 | c.804G>C p.K268N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100937599, COSV100937671; called by muse, mutect2, varscan2
- ENOSF1 | c.722C>G p.S241W (on ENST00000340116 / NM_001354066.2; = p.S193W on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99200977, COSV99201218; called by muse, mutect2, varscan2
- ESX1 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV101006406; called by muse, mutect2, varscan2
- FLT3 | c.498C>A p.Y166* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99607693; called by muse, mutect2, varscan2
- GPNMB | c.1267G>A p.E423K (on ENST00000381990 / NM_001005340.2; = p.E411K on NM_002510.3) | Missense Mutation (SNP) | VAF 81/347 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV99326306; called by muse, mutect2, varscan2
- H2BC4 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV58414927, COSV58416609, COSV58417570; called by muse, mutect2, varscan2
- HECW1 | c.3028A>G p.I1010V | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs746750028, COSV101222951; called by muse, mutect2, varscan2
- HERC1 | c.1763G>C p.G588A | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV101496385; called by muse, mutect2
- HK2 | c.2666C>G p.S889C | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs764837491, COSV99308687; called by muse, mutect2, varscan2
- IER2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as rs1157600486, COSV99460060; called by muse, mutect2
- INHBE | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763656862, COSV99875213; called by muse, mutect2, varscan2
- ITIH6 | c.1907C>A p.S636* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV54490391, COSV54494018, COSV99513038; called by muse, mutect2, varscan2
- KMT2A | c.4651C>G p.H1551D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100628138; called by muse, mutect2, varscan2
- KMT2C | c.11209G>C p.E3737Q | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100068310; called by muse, mutect2, varscan2
- LAMA2 | c.4433A>G p.N1478S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV101370210; called by muse, mutect2, varscan2
- LMNA | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100738538; called by muse, mutect2
- MAP3K6 | c.2827C>G p.Q943E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.351); catalogued as COSV100539174; called by muse, mutect2
- MBD5 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs868827314, COSV68698683; called by muse, mutect2
- MYBL2 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs149788409; called by muse, varscan2
- MYBL2 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53829267; called by muse, varscan2
- MYO16 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV51794599, COSV99193599; called by muse, mutect2, varscan2
- MYPN | c.2999G>T p.G1000V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100589645; called by muse, mutect2, varscan2
- NEDD4L | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV99893685; called by muse, mutect2, varscan2
- OPRK1 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99653761; called by muse, mutect2, varscan2
- OR8J3 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100040601; called by muse, mutect2, varscan2
- PCLO | c.12431G>T p.G4144V | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100428231; called by muse, mutect2, varscan2
- PDE6B | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99727003; called by muse, mutect2, varscan2
- PIM1 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV100998620; called by muse, mutect2, varscan2
- PIP5K1B | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV99598128; called by muse, mutect2, varscan2
- PIPOX | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546075368, COSV100037868; called by muse, mutect2, varscan2
- PLEC | c.13395G>C p.E4465D (on ENST00000322810 / NM_201380.4; = p.E4355D on NM_000445.5) | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100511612; called by muse, mutect2
- PLEC | c.13393G>A p.E4465K (on ENST00000322810 / NM_201380.4; = p.E4355K on NM_000445.5) | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.334); catalogued as rs1554670243, COSV100511617; called by muse, mutect2
- PLEC | c.13203G>C p.R4401S (on ENST00000322810 / NM_201380.4; = p.R4291S on NM_000445.5) | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV100511624; called by muse, mutect2, varscan2
- PNLIPRP3 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100982390; called by muse, mutect2, varscan2
- PRKCQ | c.597G>C p.K199N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54110847, COSV99576425; called by muse, mutect2, varscan2
- PTPN11 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as COSV100692222; called by muse, mutect2, varscan2
- REL | c.1169C>G p.S390* | Nonsense Mutation (SNP) | VAF 21/123 reads (17%) | catalogued as COSV99691892; called by muse, mutect2, varscan2
- RGL1 | c.1835C>G p.S612C (on ENST00000360851 / NM_001297672.2; = p.S647C on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV100486271; called by muse, mutect2, varscan2
- RINL | c.1633G>T p.A545S (on ENST00000591812 / NM_001195833.2; = p.A431S on NM_198445.4) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV100531023; called by muse, mutect2, varscan2
- RYR2 | c.3721G>T p.V1241F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV100768508; called by muse, mutect2, varscan2
- SAR1A | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100951547; called by muse, mutect2, varscan2
- SASH1 | c.2657C>T p.S886F | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.191); catalogued as rs765224476, COSV100820960; called by muse, mutect2
- SEC23A | c.1131C>G p.F377L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100305115; called by muse, mutect2
- SERPINB9 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV101046491; called by muse, mutect2, varscan2
- SLC45A4 | c.1685G>C p.C562S (on ENST00000517878 / NM_001286646.2; = p.C511S on NM_001080431.2) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99196651; called by muse, mutect2
- SON | c.4966G>A p.E1656K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs1387328599, COSV99277111; called by muse, mutect2
- SOX6 | c.1675G>A p.E559K (on ENST00000528429 / NM_001145819.2; = p.E532K on NM_017508.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV100321376; called by muse, mutect2, varscan2
- SPRR2D | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); catalogued as COSV100836015; called by muse, mutect2, varscan2
- SRCAP | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs748534359, COSV99349484, COSV99351815; called by muse, mutect2, varscan2
- TBXT | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV51616681, COSV51620393; called by muse, mutect2, varscan2
- TECTA | c.209A>C p.N70T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99878901; called by muse, mutect2, varscan2
- TET2 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV54417663; called by muse, mutect2, varscan2
- TMPRSS15 | c.1029G>C p.E343D | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs1261587905, COSV53043285; called by muse, mutect2, varscan2
- TOR2A | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV100262711; called by muse, mutect2
- TPRN | c.1535T>C p.L512P | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV100285715; called by muse, mutect2, varscan2
- TRPS1 | c.137C>T p.T46M (on ENST00000220888 / NM_001330599.2; = p.T59M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs746136409, COSV99628924; called by muse, mutect2, varscan2
- USP9X | c.4973del p.R1658Hfs*30 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | catalogued as COSV61066753; called by mutect2, pindel, varscan2
- VPS13A | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV100652287, COSV62432785; called by muse, mutect2
- VSIG8 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100928763; called by mutect2, varscan2
- WDSUB1 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100701766, COSV63067149; called by muse, mutect2, varscan2
- XPO5 | c.2479C>G p.P827A | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99540217, COSV99540511; called by muse, mutect2, varscan2
- ZBTB46 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99828825; called by muse, mutect2
- ZNF217 | c.3038G>A p.G1013E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs889100106, COSV100184247; called by muse, mutect2, varscan2
- ZNF333 | c.1673G>C p.G558A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468864; called by muse, mutect2
- ZNF597 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV100071909; called by muse, mutect2, varscan2
- ZNF644 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100494300; called by muse, mutect2, varscan2
- ZSCAN4 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100552404; called by muse, mutect2, varscan2
- ZSWIM5 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as COSV100655378; called by muse, mutect2, varscan2
- IGLV3-19 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ABLIM1 | c.933C>T p.C311= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV99521561; called by muse, mutect2, varscan2
- ADORA3 | c.624C>T p.L208= | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as COSV99598626; called by muse, mutect2
- AHNAK2 | c.15429G>A p.V5143= | Silent (SNP) | VAF 30/177 reads (17%) | catalogued as COSV100316016; called by muse, mutect2, varscan2
- ATCAY | c.1005G>A p.A335= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs765139204, COSV100008499, COSV56655984; called by muse, mutect2, varscan2
- ATP2B2 | c.915C>T p.D305= (on ENST00000352432; = p.D316= on NM_001001331.4) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs748937189, COSV59506172; called by muse, mutect2, varscan2
- BBS2 | c.840C>T p.I280= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs1207765703, COSV99802157; called by muse, mutect2, varscan2
- BCHE | c.1392G>T p.V464= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV100012199; called by muse, mutect2
- BEND2 | c.1395T>C p.S465= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV101191832; called by muse, mutect2, varscan2
- BTLA | c.222C>G p.L74= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV100569624; called by muse, mutect2, varscan2
- DCST1 | c.1179C>T p.F393= | Silent (SNP) | VAF 22/177 reads (12%) | catalogued as COSV99792778; called by muse, mutect2, varscan2
- DVL3 | c.756C>T p.L252= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs772473384, COSV100493551; called by muse, mutect2, varscan2
- ELOA2 | c.579C>A p.P193= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs372494802, COSV55299615, COSV99796074; called by muse, mutect2, varscan2
- FCRL5 | c.984G>A p.L328= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as COSV100708595; called by muse, mutect2
- FOXL2 | c.306C>A p.I102= | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as COSV100374381; called by muse, mutect2
- GAB2 | c.963C>T p.L321= (on ENST00000361507 / NM_080491.3; = p.L283= on NM_012296.3) | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV60866002, COSV60871833; called by muse, mutect2, varscan2
- HSPA9 | c.369C>G p.L123= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV51866859, COSV99785265; called by muse, mutect2, varscan2
- ILRUN | c.117C>T p.L39= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100927405; called by muse, mutect2
- LIX1L | c.579G>A p.E193= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV100811060; called by muse, mutect2
- LMNA | c.366G>A p.K122= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100738536; called by muse, varscan2
- MAGEB2 | c.933G>A p.L311= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100975597, COSV66782277; called by muse, mutect2, varscan2
- MBD4 | c.1101G>A p.R367= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV99958830; called by muse, mutect2, varscan2
- MCF2 | c.243C>T p.G81= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs1424847309, COSV58491324; called by muse, mutect2, varscan2
- MID2 | c.495C>T p.C165= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99464150; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2316G>A p.Q772= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100824990; called by muse, mutect2, varscan2
- MYO18B | c.1743T>C p.S581= | Silent (SNP) | VAF 35/292 reads (12%) | catalogued as rs753823178, COSV100122812; called by muse, mutect2, varscan2
- NHLRC3 | c.660A>G p.T220= | Silent (SNP) | VAF 23/319 reads (7%) | catalogued as COSV101098916; called by muse, mutect2
- NLRP11 | c.2082G>C p.L694= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV100789651; called by muse, mutect2, varscan2
- OR4K13 | c.774C>T p.Y258= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs201842923, COSV59859418, COSV59859564; called by muse, mutect2, varscan2
- PSKH1 | c.309A>G p.L103= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1436943968, COSV99344506; called by muse, mutect2, varscan2
- TOR1AIP2 | c.417C>G p.L139= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV100857306; called by muse, mutect2, varscan2
- WDR18 | c.990C>T p.F330= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs767500029, COSV99242707; called by muse, mutect2, varscan2
- WDR76 | c.1227C>T p.F409= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs776985988, COSV99776162; called by muse, mutect2, varscan2
- ZFP57 | c.105G>A p.R35= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as rs139717984, COSV65306749; called by muse, mutect2, varscan2
- ZNF786 | c.549G>A p.E183= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1322966826, COSV100302692; called by muse, mutect2
- MOGAT2 | c.*2C>T | 3'UTR (SNP) | VAF 10/90 reads (11%) | catalogued as COSV99549389; called by muse, mutect2, varscan2
- ST8SIA4 | c.798-4357A>G | Intron (SNP) | VAF 4/55 reads (7%) | catalogued as COSV99185135; called by muse, mutect2
- Unknown | chr21:16071270 C>T | IGR (SNP) | VAF 27/179 reads (15%) | called by muse, mutect2, varscan2
